Gene-level copy-number profile of tumor specimen TCGA-02-0330-01A from TCGA case TCGA-02-0330, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.1 years (18,654 days).
Specimen TCGA-02-0330-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.46c6f63b-9008-4e03-a7fd-b7ad7b4c2b70.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,140 have no estimate.
https://portal.gdc.cancer.gov/files/043f2d80-16a1-4d36-b05e-8e69c3eb2da6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,915; copy number 2: 40,497; copy number 3: 2,985; copy number 4: 3; copy number 5: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0330-01): tumor purity 0.6, ploidy 1.8, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 83 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,590,596–204,558,120, 72 genes, copy number 5 (broad region; genes not listed).
- chr12:68,686,951–68,971,570, 11 genes, copy number 5 (within-gene range 4–5): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.

Autosomal genes at a single copy (total copy number 1): 11,915. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
